Surgical pathology report (de-identified scan), TCGA case TCGA-76-4931, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Thomas Jefferson University, specimen TCGA-76-4931-01A (Primary Tumor).

[page 1 of 3]
Patient: [REDACTED]

SURGICAL PATHOLOGY REPORT

FINAL DIAGNOSIS:

1. Right temporal tumor: malignant glioma, see diagnosis for specimen #2.
2. Right temporal tumor: glioblastoma multiforme, who grade iv. see microscopic description.

[REDACTED]
Report Electronically Signed

This diagnostic report has been personally interpreted by the signatory of record.
[REDACTED]

Microscopic Description:

The tumor is composed of pleomorphic glial cells. Mitotic figures are identified in tumor cells. Areas of tumor necrosis are present. Microvascular proliferation is present focally within the tumor. A separate immunohistochemical report will be issued.

Frozen Section Diagnosis:

1. Right temporal tumor: Malignant glioma. At least grade 3. More tissue requested if clinically indicated.

Clinical History and Diagnosis:

Right temporal tumor

[page 2 of 3]
Source of Specimen:

1: Right temporal tumor

2: Right temporal tumor

Gross Description:

1. Right temporal tumor: Received fresh for frozen section are multiple fragments of soft tan tissue measuring 1.5 x 1.0 x 0.5 cm in aggregate. Touch preps are prepared. Approximately 50% of the specimen is submitted for frozen section diagnosis. The remaining specimen is entirely submitted in a total of two cassettes.

2. Right temporal tumor: Received in formalin are multiple fragments of soft tan-white tissue measuring 3.7 x 3.0 x 1.0 cm in aggregate. The specimen is serially sectioned and entirely submitted in four cassettes.

Histology Laboratory
H&E

[page 3 of 3]
[REDACTED]

Patient: [REDACTED]

IMMUNOPATHOLOGY REPORT

EVALUATION:

gfap: positive staining in tumor cells.

ki67: positive staining in up to 40% of tumor cell nuclei.

Comment:

The immunohistochemical stains support the diagnosis of glioblastoma multiforme. See corresponding surgical pathology report [REDACTED]

[REDACTED]

Report Electronically Signed

This diagnostic report has been personally interpreted by the signatory of record.

[REDACTED]

Source: NCI Genomic Data Commons file 4397242b-09c2-4e91-b241-fbee83c9582f (TCGA-76-4931.F34D64D6-6103-407F-B45B-4E660A1BFCD1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).